Gene-level copy-number profile of tumor specimen TCGA-GD-A6C6-01A from TCGA case TCGA-GD-A6C6, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 64.7 years (23,631 days).
Specimen TCGA-GD-A6C6-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.e1dc6fc2-a4a3-4609-9b47-564eef7dfc60.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GD-A6C6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cfbaeed5-95eb-4af9-b6a6-b651c11ed9e6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 98; copy number 1: 2,410; copy number 2: 20,167; copy number 3: 29,742; copy number 4: 5,458; copy number 5: 1,267; copy number 6: 213; copy number 7: 65; copy number 8: 271; copy number 10: 54; copy number 13: 47; copy number 15: 18; copy number 19: 1; copy number 21: 4; copy number 23: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GD-A6C6-01A-21D-A31K-01): tumor purity 0.92, ploidy 2.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 98 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:246,945,547–247,120,278, 9 genes (within-gene range 0–3): ZNF670-ZNF695, AL512637.2, ZNF670, AL512637.1, AL627095.1, ZNF669, AL627095.2, C1orf229, FGFR3P6.
- chr9:19,705,338–24,592,104, 89 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 461 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:6,770,001–7,741,533, 1 gene, copy number 10 (within-gene range 2–19): GRM7.
- chr3:7,241,916–12,434,356, 108 genes, copy number 8–19 (broad region; genes not listed).
- chr5:33,888,056–34,373,850, 15 genes, copy number 7: RNU6-923P, RXFP3, SLC45A2, AC139783.2, AMACR, C1QTNF3-AMACR, AC139783.1, C1QTNF3, AC139792.2, AC139792.3, AC139792.1, AC138409.2, AC138409.1, AC138409.3, AC138853.1.
- chr7:17,405,479–17,558,909, 1 gene, copy number 7 (within-gene range 4–7): AC019117.1.
- chr8:100,133,351–101,492,499, 49 genes, copy number 8–15: FBXO43, POLR2K, SPAG1, Y_RNA, AC025647.1, Y_RNA, RNF19A, AP001574.1, AP003472.1, MIR4471, AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62, SNX31, AP001205.1, RNU6-1092P, PABPC1, MIR7705, RNU6ATAC41P, Y_RNA, RPS20P23, RNU4-83P, RPS26P6, Metazoa_SRP, AC027373.1, YWHAZ, RN7SL685P, FLJ42969, AP003469.2, AP003469.1, RN7SKP249, AP003469.3, ZNNT1, ZNF706, AP001330.4, AP001330.2, LINC02844, AP001330.5, AP001330.1, RNU7-67P, AP001330.3, NACA4P, DUXAP2, LINC02845, RN7SL563P, AP001208.1, AP001207.3.
- chr11:69,414,307–70,436,584, 33 genes, copy number 7–13: AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 7: AP001271.1.
- chr11:75,815,210–76,144,232, 1 gene, copy number 8 (within-gene range 5–8): UVRAG.
- chr11:76,137,315–81,431,520, 84 genes, copy number 8–23 (within-gene range 3–23) (broad region; genes not listed).
- chr21:13,305,152–24,321,377, 168 genes, copy number 7–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,217. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
